Surgical pathology report (de-identified scan), TCGA case TCGA-95-7567, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Emory, specimen TCGA-95-7567-01A (Primary Tumor).

[page 1 of 5]
030, 2017

Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Encounter info:

* Final Report *

APRPT (Verified)

Patient Name

MRN:

Location:

Client:

Submitting

Phys:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LYMPH NODES, #7, EXCISION, A1FS, A2FS, A3FS:

- FRAGMENTED NODAL TISSUE, NEGATIVE FOR METASTATIC CARCINOMA.

B. LYMPH NODES, 4R, EXCISION, B1FS, B2FS:

- SIX LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/6).

C. LYMPH NODE, 11R, EXCISION, C1FS:

- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

D. SKIN, RIGHT POSTERIOR CHEST, EXCISION:

- SEBORRHEIC KERATOSIS.

E. LYMPH NODES, POSTERIOR 11R, EXCISION:

- TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

F. LYMPH NODE, 12R, EXCISION:

Printed by:

Printed on:

[page 2 of 5]
Anat Path Reports

* Final Report *

- FRAGMENTS OF ADENOCARCINOMA WITH DETACHED MINUTE FRAGMENT OF LYMPHOID TISSUE.

G. LUNG, RIGHT UPPER LOBE, LOBECTOMY, G1FS, G2FS:

- ADENOCARCINOMA, MIXED SUBTYPE, WITH SOLID AND MICROPAPILLARY PATTERNS.
- THE TUMOR MEASURES 6.3 x 6.3 x 5.0 CM.
- PERINEURAL INVASION IDENTIFIED.
- VISCERAL PLEURAL INVASION IS IDENTIFIED.
- RESECTION MARGINS NEGATIVE FOR CARCINOMA.
- METASTATIC CARCINOMA INVOLVING ONE OF SEVEN PERIBRONCHIAL LYMPH NODES (1/7).
- EMPHYSEMATOUS CHANGES.
- SEE SYNOPTIC REPORT.

Comment

Visceral pleural invasion is confirmed with an elastic stain.

II

Synoptic Worksheet

G. Right upper lobe:

Specimen:	Lobe(s) of lung: right upper
Procedure:	Lobectomy
Specimen Integrity:	Intact
Specimen Laterality:	Right
Tumor Site:	Upper lobe
Tumor Focality:	Unifocal
Histologic Type:	Adenocarcinoma, mixed subtype
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 6.3 cm Additional dimension: 6.3 cm Additional dimension: 5.0 cm
Visceral Pleura Invasion:	Present
Tumor Extension:	Not identified
Bronchial Margin:	Uninvolved by invasive carcinoma Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Uninvolved by invasive carcinoma
Chest Wall Margin:	Uninvolved by invasive carcinoma
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	

Printed by:
Printed on:

Page 2 of 5
(Continued)

[page 3 of 5]
Anat Path Reports

* Final Report *

Treatment Effect:	Distance of invasive carcinoma from closest margin: 5 mm
Lymph-Vascular Invasion:	Margin closest to invasive carcinoma:: bronchial and vascular margins
TNM Descriptors:	Not applicable
Primary Tumor (pT):	Not identified
Regional Lymph Nodes (pN):	Not applicable
	pT2b: Tumor greater than 5 cm, but 7 cm or less in greatest dimension
	pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including involvement by direct extension
	Involved nodal station(s): see above
Distant Metastasis (pM):	Not applicable

Clinical History

Right lung cancer. Right thoracotomy. Adenocarcinoma, right lung. Right upper lobectomy.

Specimen(s) Received

A: #7 lymph node
B: 4R lymph node
C: 11R Sump node
D: Right posterior chest lesion
E: Posterior 11R Sump
F: 12R lymph node
G: Right upper lobe

Gross Description

Specimen A is received fresh for frozen section diagnosis, labeled with the patient's name, medical record number and as "#7 lymph node." The specimen consists of multiple soft tissue fragments measuring 2.5 x 2.0 x 1.0 cm in aggregate. Multiple lymph node fragments are identified, and submitted entirely for frozen section diagnosis as "A1FS" through "A3FS." The remaining adipose tissue is submitted in cassette "A4." Dictated by

Specimen B is received fresh for intraoperative diagnosis, labeled with the patient's name, medical record number and as "4R lymph node." The specimen consists of a soft tissue fragment measuring 3.5 x 2.0 x 0.5 cm. Two lymph nodes are identified measuring 1.5 and 1.2 cm in greatest dimension, respectively. The smaller lymph node is submitted entirely for frozen section diagnosis as "B1FS" and the larger lymph node is submitted entirely for frozen section diagnosis as "B2FS." The remaining adipose tissue is submitted in cassette "B3" and "B4." Dictated by

Specimen C is received fresh for intraoperative consultation and is labeled "11R sump node." It consists of a single lymph node measuring 1.8 x 0.8 x 0.4 cm. The specimen is submitted entirely for frozen section diagnosis in cassette "C1FS." This frozen was done by

Specimen D consists of a skin ellipse measuring 5.0 x 1.1 cm excised to a depth of 1.2 cm. A crusted round lesion is present on the skin surface measuring 1.4 x 0.9 cm and located less than 1.0 mm from one resection edge and 2.0 mm from the opposite resection edge. Representative sections of the specimen are submitted as described below.

D1: Skin tip

Printed by:
Printed on:

Page 3 of 5
(Continued)

[page 4 of 5]
Anat Path Reports

* Final Report *

D2: Opposite skin tip
D3-5: Lesional area, serially sectioned

Specimen E is received in formalin, labeled with the patient's name, medical record number and "posterior 11R sump." The specimen consists of a fragment of soft tissue measuring 1.3 x 1.0 x 0.9 cm. The specimen is entirely submitted in cassette "E1."

Specimen F is received in formalin, labeled with the patient's name, medical record number and "12R lymph node." The specimen consists of soft tissue measuring 1.4 x 1.2 x 0.9 cm. The specimen is entirely submitted in cassette "F1." (Dictated by

Specimen G is received fresh for intraoperative consultation and labeled with the patient's name, medical record number and as "right upper lobe". The specimen consists of a lobe of lung measuring 18.0 x 9.0 x 7.5 cm, weighing 325 grams. A firm tumor with irregular border and necrosis is present in the hilar invading the bronchus measuring 6.3 x 6.3 x 5.0 cm. The tumor is 0.5 cm from the bronchial and vascular margins, and abuts the pleura. Parietal pleura is focally adhered to the posterior lung, and is identified by the surgeon, and inked blue. This area is 3.5 cm from tumor. A slightly firm nodule is present on the visceral pleura adjacent to the parietal pleura measuring 0.6 x 0.4 x 0.3 cm. The remaining lung is unremarkable. The shave bronchial margin is submitted for frozen section diagnosis as "G1FS." A representative section of the tumor is submitted for frozen section diagnosis as "G2FS;" and a touch prep of the tumor is submitted as "G2TP." The specimen is inked as follows: visceral pleura black, parietal pleura blue. Representative sections of the tumor and normal lung are submitted for Tissue Procurement. (Dictated by

G1FS: Bronchial margin, shave
G2FS: Representative section of tumor
G3: Vascular margins
G4: Tumor in relation to bronchus
G5: Tumor in relation to visceral pleura
G6,7: Representative sections of the tumor
G8: Representative sections of parietal pleura and visceral pleural nodule
G9: Representative sections of uninvolved lung
G10: One peribronchial lymph node, bisected
G11: One peribronchial lymph node, bisected
G12: Two peribronchial lymph nodes
G13: One peribronchial lymph node, bisected
G14,15: One peribronchial lymph node, bisected

Intraoperative Consult Diagnosis

A1FS-A3FS: #7 LYMPH NODE (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

B1FS,B2FS: 4R LYMPH NODE (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

C1FS: 11R NODE (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

G1FS: BRONCHIAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
Anat Path Reports

* Final Report *

G2FS,G2TP: TUMOR (FROZEN SECTION): ADENOCARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

Pathologist:

Microscopic Description

Microscopic examination has been performed.

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Source: NCI Genomic Data Commons file 614a5cea-18c0-474c-a134-0300299debda (TCGA-95-7567.7B2574CB-FF02-4E3E-B64B-9D0265EF9335.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).